Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAXX, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAXX-01A (Primary Tumor).

[page 1 of 2]
Patient Name

MRN:

DOB: (Age:)

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: Thymus gland, Thymoma and Pericardium

DIAGNOSIS

1. Thymus, resection (thymus and portion of pericardium):

a) Thymoma, WHO type B2, with: (see Comment)

i) Greatest dimension = 5.5 cm

ii) Multifocal microscopic invasion into mediastinal fat

iii) Invasion of pericardium not identified

iv) Tumor present microscopically at a cauterized edge/margin

of resection

b) Residual thymic tissue with minimal involutional changes

SYNOPTIC DATA

Specimen Type:

Tumor Site:

Tumor Size:

Histologic Type:

Pathologic Staging:
invasion

Regional Lymph Nodes:

Distant Metastasis:

Margins:

Other: thymectomy

Thymus

Greatest dimension: 5.5 cm

Type B thymoma, B2 (cortical)

Stage IIa: Microscopic transcapsular

pNX: Cannot be assessed

Cannot be assessed

Margin(s) involved by tumor

Margin(s): soft tissue

COMMENT

Sections show a well-circumscribed tumor composed of a roughly equal admixture of small lymphocytes and larger epithelial cells. The tumor is partially encapsulated, but in several places extends through the capsule

Status: complete

Page: 1 of 2

ICD-O-3
Thymoma, type B2, malignant
8584h3
Site: Thymus
C379
Q606/114

[page 2 of 2]
Patient Name:

MRN:

DOB: Age:)

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

into adjacent adipose tissue. Tumor is present focally at a cauterized edge of resection, presumably a surgical margin. By immunohistochemistry, the lymphocytes stain positive for CD3, with a subset positive for CD1a, and the epithelial cells stain positive for low and high molecular weight keratins and p63. The overall features are in keeping with a minimally invasive thymoma (modified Masaoka stage IIa), WHO type B2 (aka cortical type), with a microscopically positive margin of resection.

ELECTRONICALLY VERIFIED BY:

GROSS DESCRIPTION

1. The specimen container is labeled with the patient's name and as "thymus gland, thymoma and pericardium" and contains an unoriented thymus gland with a portion of membranous tissue (?pericardium) received in 10% buffered formalin. The thymus gland measures 12.5 x 8.5 x 2.4 cm. The membranous tissue measures 7.5 x 2.5 x 0.2 cm. The specimen is painted with silver nitrate, with the ?pericardium over coat the green dye. On gross examination, a well-circumscribed nodule is identified on one pole of the thymus measuring 5.5 x 3.8 x 2.5 cm. The cut surface of the nodule is tan in color, with focal areas of calcification. The peripheral aspect of the nodule firm and is centrally soft and friable. The rest of the thymus is firm, tan in color and has a slightly nodular appearance.

1A-1E representative section nodule

1F-1J representative sections thymus

Status: complete

Page: 2 of 2

Source: NCI Genomic Data Commons file 36aceec5-b511-4d81-98d4-84449bcf374f (TCGA-XU-AAXX.045A3F6C-6992-4BFC-A588-AF588A9EF294.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).